Surgical pathology report (de-identified scan), TCGA case TCGA-PZ-A5RE, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site  ABS - Lahey Clinic, specimen TCGA-PZ-A5RE-01A (Primary Tumor).

[page 1 of 4]
Gender

F

Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected

Time Reported

Ordering Provider

Status

Final

Results

Final

Source of Specimen

PANCREATIC DUODENECTOMY SEE WORKSHEET-

FINAL DIAGNOSIS:

PANCREATIC DUODENECTOMY SEE WORKSHEET-

INVASIVE ADENOCARCINOMA OF PANCREAS WITH TRANSMURAL INVOLVEMENT OF THE DUODENUM, see note.

INVASION OF PERIPANCREATIC SOFT TISSUE: IS PRESENT.

TUMOR INVADES THE WALL OF SUPERIOR MESENTERIC VEIN. NO INTRALUMINAL TUMOR THROMBUS SEEN.

HISTOLOGIC TYPE: DUCTAL ADENOCARCINOMA WITH FOCAL MUCINOUS FEATURES. *per TSS, mucinous features = 9%.*

HISTOLOGIC GRADE: 2-3/4.

TUMOR SIZE: 3.0 CM.

TUMOR FOCALITY: UNIFOCAL.

TUMOR SITE: HEAD OF PANCREAS.

TREATMENT EFFECT: N/A.

SPECIMEN TYPE: PYLORUS-SPARING PANCREATODUODENECTOMY.

THREE OF TWENTY TWO PERIPANCREATIC NODES: POSITIVE FOR

*ICD-0-3
adenocarcinoma, duct, NOS 8500/3
Site: pancreas, head C25.0*

*fw
2/17/13*

[page 2 of 4]
METASTATIC DISEASE.

TNM STAGE: pT3, pN1, pMX.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED: 3
NUMBER EXAMINED: 22

LYMPHATIC (SMALL VESSEL) INVASION: IS SEEN.

PERINEURAL INVASION: IS SEEN.

MARGINS: TUMOR IS FOCALLY CLOSE (<1 mm) TO THE INKED SOFT TISSUE MARGIN IN THE AREA OF SUPERIOR MESENTERIC VEIN (marked with suture).

PANCREATIC PARENCHYMAL, DUODENAL AND COMMON BILE DUCT MARGINS ARE NEGATIVE FOR CARCINOMA.

Note: Tumor extends into duodenal wall and infiltrates the periampullary mucosa where it extends to the surface and becomes ulcerated. Since the bulk of the tumor is located in the pancreatic head/uncinate process, adenocarcinoma of pancreatic origin is favored over a small bowel or ampullary primary.

Signature

Case Clinical Information
CARCINOMA OF PANCREAS

Gross Description

Received in formalin labeled with the patient's name and "pancreatic duodenectomy" is a previously dissected specimen so designated with the included loop of duodenum measuring 17 cm along the greater curve. The proximal margin reveals a staple closure and appears pylorus-sparing and demonstrates a circumference of 4.5 cm. The proximal staple line is removed and the freshly exposed surface is lightly inked blue. The distal duodenum reveals a staple closure as well and a circumference of 5 cm with the circumference measuring 4.5 cm at the level of the ampulla. The common duct has been previously opened and measures 5.5 cm in length with a proximal circumference of 2 cm diminishing to 0.8 cm at the ampulla. The mucosa of the common duct is relatively smooth and yellow/tan. The duodenum in the area of the ampulla reveals a discrete area of induration and effacement over an area measuring 2 x 1.5 cm which corresponds to a relatively well-demarcated, firm and

[page 3 of 4]
yellow/tan mass occupying the head of the pancreas with the mass measuring 3 x 3 x 3 cm in greatest dimensions. The pancreatic resection margin measures 3.3 x 1.5 cm and has been previously inked black. The pancreas itself measures overall 6 cm superior to inferior x 3.5 cm right to left x 4.5 cm anterior to posterior. Soft tissue inferior to the pancreas has been previously inked black in a ragged area where there is a suture designated as identifying a portion of superior mesenteric vein. This area of tissue is indurated and continuous with the previously described inferior pancreatic tumor. The tumor is separated from the pancreatic resection margin by a minimum of 2 cm grossly normal pancreas. The section code is as follows: A1=shave of pancreatic resection margin; A2=shave of distal duodenal margin; A3=proximal duodenum parallel to the lumen, posterior, with proximal aspect inked blue after removing staple closure; A4=shave of proximal common duct resection margin; A5-A10=sutured area indicating superior mesenteric vein remnant, blocked out, serially sectioned perpendicular to surface and totally submitted (note that vein is not recognized grossly); A11-A13=apparently ulcerated duodenum overlying pancreatic tumor; A14=duplicate cross-sections of proximal common duct not to include resection margin; A15, A16=ampulla of Vater adjacent to overlying tumor parallel to lumen of common duct; A17, A18=additional sections of tumor not to include resection margin; A19-A20 and A21-A22=two dominant lymph nodes serially sectioned and totally submitted, two cassettes each; A23, A24=two additional lymph nodes, serially sectioned and totally submitted, separate cassettes; and A25-A28=additional potential lymph nodes from periductal area.

Physicians

Procedure

- A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.4
H&E X1 A RECUTS
- A. AA ROUTINE H&E X1 BLOCK.5
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.6
H&E X1 AA RECUT
- A. AA ROUTINE H&E X1 BLOCK.7
-

[page 4 of 4]
H&E X1 AA RECUT
A. AA ROUTINE H&E X1 BLOCK.8
H&E X1
A. AA ROUTINE H&E X1 BLOCK.9
H&E X1
A. AA ROUTINE H&E X1 BLOCK.10
H&E X1 AA RECUT
A. AA ROUTINE H&E X1 BLOCK.11
H&E X1
A. AA ROUTINE H&E X1 BLOCK.12
H&E X1
A. AA ROUTINE H&E X1 BLOCK.13
H&E X1
A. AA ROUTINE H&E X1 BLOCK.14
H&E X1
A. AA ROUTINE H&E X1 BLOCK.15
H&E X1
A. AA ROUTINE H&E X1 BLOCK.16
H&E X1
A. AA ROUTINE H&E X1 BLOCK.17
H&E X1
A. AA ROUTINE H&E X1 BLOCK.18
H&E X1
A. AA ROUTINE H&E X1 BLOCK.19
H&E X1
A. AA ROUTINE H&E X1 BLOCK.20
H&E X1
A. AA ROUTINE H&E X1 BLOCK.21
H&E X1
A. AA ROUTINE H&E X1 BLOCK.22
H&E X1
A. AA ROUTINE H&E X1 BLOCK.23
H&E X1
A. AA ROUTINE H&E X1 BLOCK.24
H&E X1
A. AA ROUTINE H&E X1 BLOCK.25
H&E X1
A. AA ROUTINE H&E X1 BLOCK.26
H&E X1
A. AA ROUTINE H&E X1 BLOCK.27
H&E X1
A. AA ROUTINE H&E X1 BLOCK.28
H&E X1

Prepa.

W 2/17/13
2/17/13

Source: NCI Genomic Data Commons file e0f96540-bb15-4279-a605-a2f36a5ba7f0 (TCGA-PZ-A5RE.ABDE8ADA-A016-48A6-89F6-AC3BCB79B943.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).